Somatic mutation profile of tumor specimen TCGA-ZG-A9MC-01A (aliquot TCGA-ZG-A9MC-01A-31D-A41K-08) from TCGA case TCGA-ZG-A9MC, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.8 years (25,477 days).
Specimen TCGA-ZG-A9MC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b866b3e-6622-4eb7-8546-a25b1458548e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9MC-10A (Blood Derived Normal), aliquot TCGA-ZG-A9MC-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820e1bbc-1780-4506-8216-546fa40aa9a8

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DISP3 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV53824405, COSV99607212; called by muse, mutect2, varscan2
- FAM135B | c.2838C>G p.I946M | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99419481; called by muse, mutect2
- GABRP | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174225730, COSV99516569; called by muse, mutect2, varscan2
- IFT172 | c.4682C>G p.S1561C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV99274813; called by muse, mutect2
- LDLRAP1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs1252839122, COSV100974684; called by muse, mutect2
- MED11 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs559815092, COSV99543401; called by mutect2, varscan2
- NALCN | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761378515, COSV99213220; called by mutect2, varscan2
- NFATC1 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500702; called by muse, mutect2
- NGF | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101049352; called by muse, mutect2
- NYNRIN | c.3380A>C p.D1127A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV101230510; called by muse, mutect2, varscan2
- OR10C1 | c.233C>T p.T78M (on ENST00000622521; = p.T76M on NM_013941.3) | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.37); catalogued as COSV101010795; called by muse, varscan2
- P2RY2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100232628; called by muse, mutect2
- PCDHAC2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV53843354; called by muse, mutect2
- PTPN5 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs753563589, COSV100659685; called by muse, mutect2, varscan2
- RYR1 | c.5177G>A p.R1726H | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1283664977, COSV62104639; called by muse, mutect2
- SPANXN5 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.192); catalogued as rs150967779, COSV100973938; called by muse, mutect2, varscan2
- SYT9 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100607597; called by muse, mutect2
- TNPO2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100790286; called by muse, mutect2
- ZNF646 | c.2549G>A p.C850Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889059621, COSV99762038; called by muse, mutect2, varscan2
- KMT2D | c.10312G>T p.V3438L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PIP4K2B | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2
- SRPK3 | c.1115del p.Q372Rfs*21 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, varscan2
- COP1 | c.1719C>T p.F573= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs776140400, COSV58175404; called by muse, mutect2, varscan2
- MARCHF1 | c.189T>C p.A63= (on ENST00000274056; = p.A46= on NM_017923.4) | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV99920080; called by muse, mutect2
- PCDHB7 | c.714C>T p.N238= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs782421028, COSV50760211; called by muse, mutect2
- RPUSD1 | c.645C>T p.I215= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99135612; called by muse, mutect2, varscan2
